Surgical pathology report (de-identified scan), TCGA case TCGA-UB-AA0U, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UCSF, specimen TCGA-UB-AA0U-01A (Primary Tumor).

[page 1 of 5]
Results

Result Information

Status (Last updated Date/Time)

Final result

Accession #

ICD-O-3
Carcinoma, hepatocellular
NOS 8170/3

Site: Liver C22.0
J4 4/14/14

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED])
Sex: Male
Soc. Sec. #: [REDACTED]
Accession #: [REDACTED]
Visit #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Location: [REDACTED]
Client: [REDACTED]
Physician(s): [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

A. Liver, left lateral segment, core needle biopsy: Scant fragment of atypical hepatic tissue; see comment.

B. Liver, left lateral segment, partial hepatectomy:

1. Hepatocellular carcinoma, moderately-differentiated, multifocal, largest lesion measuring 4.1 cm, with focal disruption of the capsule, present at inked surgical margin; see comment.
2. Mild steatosis and mild siderosis.

COMMENT:

Sections show multifocal tumor composed of nests and widened trabecular of hepatoid cells with focal pseudoacinar and small cell change suggestive of hepatocellular carcinoma. No intratumoral bile is noted. Background liver shows mild steatosis and rare swollen cells, but no definite ballooned hepatocytes or Mallory hyaline.

For the complete evaluation of this case special stains for mucicarmine and reticulin were performed on block B5; stains for iron and trichrome were performed on block B7. Immunohistochemical stains for CK7, synaptophysin, arginase-1, and CK19 were performed on block B5 and evaluated at the

Arginase-1 is positive in tumor cells, and reticulin staining highlights

[page 2 of 5]
thickened hepatocyte plates within the tumor, consistent with a moderately differentiated hepatocellular carcinoma (HCC). The tumor cells are negative for mucicarmine and CK19, arguing against mixed HCC/cholangiocarcinoma, but there is focal CK7 labeling, a non-specific finding. Synaptophysin is negative, excluding a neuroendocrine tumor.

Trichrome staining of a subcapsular area of uninvolved liver (block B7) showed no significant fibrosis that could not be explained by peritumoral effect or subcapsular location. Iron staining of the same area demonstrated mild siderosis (1+, scale 0-4+) in hepatocytes, which does not suggest untreated hereditary hemochromatosis.

Liver Tumor, Including Intrahepatic Bile Duct, Synoptic Comment

- Tumor type: Hepatocellular carcinoma.
- Histologic grade: Moderately differentiated.
- Tumor size (maximum diameter of largest lesion): 4.1 cm.
- Tumor necrosis: <30%.
- Multifocality (more than one tumor separated by nontumorous liver parenchyma): Present.
- Estimated total tumor diameter of all HCC foci: total diameter 6.0 cm.
- Vascular invasion: None.
- Hepatic capsule: Tumor abuts the capsule at multiple locations. Focally, the capsule is disrupted over tumor, with ink on tumor. The finding is concerning for tumor extension through the capsule, although not definitive. Per the operative note, a biopsy of the tumor was taken intraoperatively, thus is it possible that this area of capsular disruption represents the biopsy site. Correlation with the operative findings is required.
- Local extension of tumor: Confined to liver, but there is capsular disruption and clinical correlation is suggested.
- Hepatic surgical margins: Positive; tumor is at the inked surgical parenchymal margin (best appreciated on FS2B).
- Non-neoplastic liver: Mild steatosis (grade 1, scale 0-3), mild siderosis (grade 1, scale 0-4).
- Lymph node status: None submitted.
- AJCC Stage: At least pT2NX; pT4NX if the capsular disruption represents extension beyond the visceral epithelium. Correlation with operative findings is required.

Specimen(s) Received

A: Left lateral segment Liver lesion (fs1)
B: Left lateral segment Liver (fs2)

Intraoperative Diagnosis

FS1 (A) Liver, left lateral, biopsy: Hepatic tissue with cytologic and architectural atypia on a limited biopsy. Definitive diagnosis requires immunohistochemical staining Dr. agrees. (Dr.

FS2 (B) Liver, left lateral, removal of segment: Hepatocellular carcinoma, low grade on representative section, present at inked margin. Dr.

[page 3 of 5]
Clinical History

The patient is a year-old male who presented with a neck mass, which was found to be desmoid fibromatosis, for which he underwent partial debulking. As part of the workup, abdominal imaging was performed which demonstrated a liver mass. He has no known history of liver disease, HBV, HCV, or fatty liver disease. He does not drink heavily. He is moderately overweight, but has no history of diabetes mellitus. The patient now undergoes left lateral segmental hepatic resection.

Gross Description

The case is received in two parts, each labeled with the patient's name and medical record number.

Part A is received fresh and additionally labeled "L lat segment lesion," and consists of three 0.1-cm-thick cores of pale-tan to brown tissue. The cores each have a length of 0.3 cm, 0.5 cm and 0.5 cm. The specimen is entirely frozen for frozen section diagnosis 1 and submitted for permanent section in cassette A1.

Part B is received fresh and additionally labeled "left lateral segmental liver."

SPECIMEN TYPE: Portion of liver.

WEIGHT: 241 gm.

SIZE OF SPECIMEN: 16 x 7 x 5 cm.

GROSS ABNORMALITIES: There is a multilobulated, tan-brown mass measuring 4.1 x 3.6 x 3.4 cm, grossly abutting the capsular surface (inked blue) and located 0.6 cm from the inked cauterized margin (inked black). There are several additional satellite nodules which are grossly not connected to the primary mass. There is a 1.0 cm nodule which abuts the black ink, and a portion of this nodule is used for frozen section diagnosis FS2B. There are additional satellite nodules measuring 0.6 cm at 1.9 cm from the inked cauterized margin, and 0.3 cm at 1.8 cm from the inked cauterized margin and grossly confluent with the serosal surface. The remaining liver parenchyma is red-brown, firm and unremarkable.

ORIENTED BY: None.

INKING:

- Serosal surface: Blue.
- Cauterized margin: Black.

CASSETTES: Representative sections are submitted as follows:

B1: Frozen section remnant, FS2B.

B2: Additional cross-section of nodule at inked cauterized margin (unfrozen portion) and more distal unconnected multilobulated mass.

B3: Cross-sections of additional unconnected nodules.

B4: Cross-section of primary tumor with lobules adjacent to inked serosa.

B5: Lobules of tumor at inked serosa.

B6: Additional cross-section of tumor with inked cauterized margin.

B7: Adjacent uninvolved liver.

The immunohistochemical stains reported above were developed and their performance characteristics determined by the Department of Pathology. They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such

[page 4 of 5]
clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations, including prosector work, and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Electronically signed out on

Pathology PDF Report

[Show images for Surgical Pathology](#)

Authorizing Provider Information

Name:

Fax:

Phone:

Pager:

Signed by

Signed

Date/Time

Phone

Pager

Result History

SURGICAL PATHOLOGY

[Order Result History Report.](#)

and Items

[Surgical Pathology \(Order #](#)

This is NOT a Requisition. Requisition hyperlink below.

Surgical Pathology (Order

Pathology and Cytology

Authorizing:

MD

Date:

Release

Order:

Department:

nages

[Show images for Surgical Pathology](#)

Order Information

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Release Information

Released On

Released By

Order Details

Frequency
Once

Duration
1 occurrence

Priority
Routine

Order Class
Normal

Lab Collection and Receipt Information

Collect Date

Collect Time

Collected By

Lab Receipt Date

Lab Receipt Time

[page 5 of 5]
Collection Information

Resulting Agency

Order Provider Info

	Office phone	Pager/beeper	E-mail
Ordering User	--	--	--
Authorizing Provider			--
Billing Provider			--

Electronically Signed By:

Electronically Authorized By

Electronically Ordered By

Order Status for: SURGICAL PATHOLOGY

Parent Status: Completed

Child Orders

(This order does not yet have any children)

Order Requisition

Surgical Pathology (Order

Printed by

Criteria	W 12/20/13	Yes	No

Source: NCI Genomic Data Commons file 1acda601-62cf-465b-ab45-2a7e04d3665a (TCGA-UB-AA0U.00C0CD33-615E-47A6-8CEF-EE3A67F277D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).